Somatic mutation profile of tumor specimen HCM-SANG-0287-C20-01A (aliquot HCM-SANG-0287-C20-01A-01D-A78U-36) from HCMI case HCM-SANG-0287-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0287-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e8befcb-1046-437c-ad34-ca73bd74a157.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0287-C20-10A (Blood Derived Normal), aliquot HCM-SANG-0287-C20-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f0b848-2232-48f6-b19e-dc1e23534d48

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLAC9 | c.*76C>T | 3'UTR (SNP) | VAF 15/283 reads (5%) | catalogued as rs1394175201; called by muse, mutect2
